RC case RC-B6S4 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/522c26f8-42a6-485e-b74c-08628a5ec96f

Demographics
Sex at birth: female; Race: white; Year of birth: 1942; Vital status: Dead; Days to death: 475 days (1.3 years); Year of death: 2020; Cause of death: Not Cancer Related.

Diagnoses (2)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 76.6 years (27,985 days); Year of diagnosis: 2019; Method of diagnosis: Core Biopsy; Prior malignancy: no; Synchronous malignancy: No; International Prognostic Index (IPI): Low Risk; Sites of involvement: Bone marrow.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 189 days; Days to treatment end: 256 days; Number of cycles: 15; Treatment outcome: Complete Response; Reason treatment ended: Adverse Event; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Progressive Disease; Days to treatment start: 438 days (1.2 years); Days to treatment end: 445 days (1.2 years); Number of cycles: 3; Treatment outcome: Stable Disease; Reason treatment ended: Adverse Event; Timepoint category: Post Initial Treatment.
   Recorded as not given: Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 77.7 years (28,385 days); Days to diagnosis: 400 days (1.1 years).

Follow-up (3 entries)
- Days to follow up: 288 days; Disease response: Tumor Free.
- Day 400 (recurrence): Progression or recurrence: Yes; Days to recurrence: 400 days (1.1 years).
- Follow-up contact recording only the day: day 475.

Molecular and laboratory tests
- Lactate Dehydrogenase 293 U/L [Blood test normal range upper: 214].

Biospecimens (2 samples)
- Sample RC-B6S4-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6S4-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
